Somatic mutation profile of cancer-model specimen HCM-SANG-0310-C15-85A (3D Organoid; aliquot HCM-SANG-0310-C15-85A-01D-A78U-36), derived from the primary tumor of HCMI case HCM-SANG-0310-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0310-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4465aea6-a99f-4cf6-935d-6aaa85314da9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0310-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0310-C15-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce8eafb7-a7ef-48f9-9ac3-189fe409b084

The open-access MAF lists 190 somatic variants for this specimen: 130 protein-altering or splice-affecting, 33 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 33, Intron 11, Splice Site 8, 3'UTR 7, Frame Shift Del 6, Nonsense Mutation 4, RNA 3, 3'Flank 3, In Frame Del 2, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 58/245 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 141/141 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ARMCX3 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868995472, COSV100362190; called by muse, mutect2, varscan2
- CCDC88A | c.5239C>T p.R1747W (on ENST00000436346 / NM_001365480.1; = p.R1719W on NM_018084.5) | Missense Mutation (SNP) | VAF 178/275 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as rs371735739; called by muse, mutect2, varscan2
- CNTNAP3B | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 162/459 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs2935316; called by muse, mutect2, varscan2
- COL8A1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs777725434, COSV53729747; called by muse, mutect2, varscan2
- CPNE1 | c.847C>G p.Q283E (on ENST00000352393; = p.Q288E on NM_003915.5) | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV100467971; called by muse, mutect2, varscan2
- CR1 | c.923G>A p.R308H (on ENST00000367051; = p.R758H on NM_000651.6) | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs989786536; called by muse, mutect2, varscan2
- EBF1 | c.1128A>C p.E376D | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV58166123; called by muse, mutect2, varscan2
- EIF2AK1 | c.1463del p.T488Sfs*34 | Frame Shift Del (DEL) | VAF 105/296 reads (35%) | catalogued as COSV52235862, COSV52242724; called by mutect2, pindel, varscan2
- EXD3 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs577049845, COSV59808510, COSV59808802; called by muse, mutect2, varscan2
- FAT4 | c.7523C>T p.S2508L | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs267600010, COSV58702558; called by muse, mutect2, varscan2
- GFRA2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1457912175, CM1510817; called by muse, mutect2, varscan2
- GIMAP5 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs533934192; called by muse, mutect2, varscan2
- GOLGA8K | c.1442A>G p.H481R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1204753991; called by mutect2, varscan2
- HMG20A | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 53/100 reads (53%) | catalogued as rs1263163087; called by muse, mutect2, varscan2
- HTR3C | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs369321709, COSV59177853; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as rs766731472; called by muse, mutect2, varscan2
- KCNA5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 176/358 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52904231; called by muse, mutect2, varscan2
- KCND2 | c.1301G>C p.R434P | Missense Mutation (SNP) | VAF 139/309 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV58582332; called by muse, mutect2, varscan2
- MUC5AC | c.13912G>A p.D4638N | Missense Mutation (SNP) | VAF 149/281 reads (53%) | SIFT deleterious (0); catalogued as rs569068445; called by muse, mutect2, varscan2
- NRDC | c.1822dup p.R608Kfs*4 | Frame Shift Ins (INS) | VAF 19/49 reads (39%) | catalogued as rs767087523; called by mutect2, pindel, varscan2
- NTSR1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 121/515 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372116403; called by muse, mutect2, varscan2
- NUB1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 100/100 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs370093318; called by muse, mutect2, varscan2
- OR2T1 | c.881A>C p.K294T | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV63541165; called by muse, mutect2, varscan2
- OR4C16 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199938003, COSV58942583; called by muse, mutect2, varscan2
- OR6N2 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100210364, COSV59410636; called by muse, mutect2, varscan2
- P4HA3 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 254/366 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs756005378, COSV100525927; called by muse, mutect2, varscan2
- POLL | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1447671878; called by muse, mutect2, varscan2
- PREX2 | c.3482G>A p.C1161Y | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs917716947, COSV55788356; called by muse, mutect2, varscan2
- RABEPK | c.761_762del p.H254Rfs*30 | Frame Shift Del (DEL) | VAF 92/182 reads (51%) | catalogued as rs777035658; called by mutect2, pindel, varscan2
- RHBG | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 124/306 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1409098664, COSV54801855; called by muse, mutect2, varscan2
- RPL10L | c.235A>C p.S79R | Missense Mutation (SNP) | VAF 151/306 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV53560159; called by muse, mutect2, varscan2
- SCPEP1 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.721); catalogued as rs764552208; called by muse, mutect2, varscan2
- SEMA5B | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs781619342; called by muse, mutect2, varscan2
- SPTA1 | c.5192A>T p.E1731V | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV63754427; called by muse, mutect2, varscan2
- STAB1 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs150259424; called by muse, mutect2, varscan2
- TRIO | c.5668-2A>T p.X1890_splice | Splice Site (SNP) | VAF 168/364 reads (46%) | catalogued as COSV60079290; called by muse, mutect2, varscan2
- TRPC6 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 84/394 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV60250799; called by muse, mutect2, varscan2
- VEGFC | c.978C>G p.S326R | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV54596083, COSV99710395; called by muse, mutect2, varscan2
- ZMYM6 | c.1594C>G p.R532G | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as COSV100593196; called by muse, mutect2, varscan2
- ZNF366 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 143/301 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs151140704; called by muse, mutect2, varscan2
- ZNF776 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 114/330 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV57815356; called by muse, mutect2, varscan2
- ZNF85 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 95/183 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV100060236; called by muse, mutect2, varscan2
- AC136428.1 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ACSS2 | c.375-1G>A p.X125_splice | Splice Site (SNP) | VAF 97/276 reads (35%) | called by muse, mutect2, varscan2
- ADCY1 | c.1373A>G p.Y458C | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.17144T>A p.V5715E | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- AHRR | c.352-1G>A p.X118_splice | Splice Site (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- ALDOA | c.397C>G p.L133V (on ENST00000642816 / NM_001243177.4; = p.L79V on NM_184041.5) | Missense Mutation (SNP) | VAF 167/783 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- C1orf167 | c.2120C>A p.A707D | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- CACNA1A | c.5239T>G p.F1747V | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CACNA1E | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 145/323 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASTOR1 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CC2D1B | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 121/243 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CCDC146 | c.1920-2A>G p.X640_splice | Splice Site (SNP) | VAF 42/58 reads (72%) | called by muse, mutect2
- CCDC175 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 70/166 reads (42%) | called by muse, mutect2, varscan2
- CEACAM5 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHD1L | c.778A>T p.R260W | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHFR | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA3 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 75/75 reads (100%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- DDI1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 100/229 reads (44%) | called by muse, mutect2, varscan2
- DNAH12 | c.6216_6219+2del p.X2072_splice (on ENST00000351747; = p.X2091_splice on NM_001366028.2) | Splice Site (DEL) | VAF 33/49 reads (67%) | called by mutect2, pindel, varscan2
- DNHD1 | c.8729C>T p.A2910V | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EP300 | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESYT2 | c.1820A>T p.E607V (on ENST00000613624; = p.E531V on NM_020728.3) | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- EVI5L | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 119/533 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM135B | c.1370G>T p.R457M | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FRZB | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2
- GIGYF1 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GLCE | c.213_215del p.Q72del | In Frame Del (DEL) | VAF 44/116 reads (38%) | called by pindel, varscan2
- GPC3 | c.303G>C p.K101N | Missense Mutation (SNP) | VAF 259/259 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GPR26 | c.698A>C p.K233T | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- HNRNPUL1 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 128/198 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- HOXA4 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HP1BP3 | c.1332_1334del p.E444del | In Frame Del (DEL) | VAF 48/124 reads (39%) | called by pindel, varscan2
- ITGA8 | c.1099A>C p.S367R | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- KIAA1549L | c.4829C>A p.T1610N (on ENST00000321505; = p.T1907N on NM_012194.3) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2
- KIF21B | c.4199C>G p.A1400G (on ENST00000422435 / NM_001252100.2; = p.A1387G on NM_017596.4) | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIZ | c.936G>C p.E312D | Missense Mutation (SNP) | VAF 108/395 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2
- KIZ | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 110/395 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- LIMCH1 | c.168-1G>T p.X56_splice | Splice Site (SNP) | VAF 163/163 reads (100%) | called by muse, mutect2, varscan2
- LIPI | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 141/382 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- LRIG1 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 73/314 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRIT3 | c.1535A>C p.N512T | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LRTM1 | c.719T>A p.V240E | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- MAGEC1 | c.110T>G p.I37S | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K15 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- METAP2 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MIEF2 | c.555_585delinsCC p.L186Pfs*36 | Frame Shift Del (DEL) | VAF 48/50 reads (96%) | called by pindel, varscan2*
- MITF | c.1298C>T p.A433V (on ENST00000448226 / NM_006722.3; = p.A333V on NM_000248.4) | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MROH9 | c.1736C>T p.T579I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- MRPL47 | c.539A>T p.K180M | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MTDH | c.1127A>T p.D376V | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTMR4 | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAPRT | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 137/421 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- NEIL2 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- NEIL2 | c.461A>T p.K154M | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPAP1 | c.2489del p.P830Lfs*62 | Frame Shift Del (DEL) | VAF 53/268 reads (20%) | called by mutect2, pindel, varscan2
- OGT | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- OR1A1 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- OR2T3 | c.948A>C p.Q316H | Missense Mutation (SNP) | VAF 82/436 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T34 | c.948A>C p.Q316H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSM | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PCDHGB2 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 113/483 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PDHB | c.700+2T>C p.X234_splice | Splice Site (SNP) | VAF 125/269 reads (46%) | called by muse, mutect2, varscan2
- PIP5K1A | c.833T>A p.L278H (on ENST00000368888 / NM_001135638.2; = p.L265H on NM_003557.3) | Missense Mutation (SNP) | VAF 74/706 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PIWIL4 | c.1622A>T p.D541V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PRICKLE4 | c.605A>G p.E202G (on ENST00000359201; = p.E242G on NM_013397.6) | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PTPRQ | c.5356G>A p.A1786T (on ENST00000616559; = p.A1744T on NM_001145026.2) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RARA | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 206/405 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RELN | c.2003-1G>A p.X668_splice | Splice Site (SNP) | VAF 125/293 reads (43%) | called by muse, mutect2, varscan2
- RGS4 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF207 | c.635A>T p.K212M | Missense Mutation (SNP) | VAF 116/394 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SH2D3C | c.629T>A p.L210H (on ENST00000314830 / NM_170600.3; = p.L53H on NM_005489.4) | Missense Mutation (SNP) | VAF 71/752 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SIGLEC12 | c.911C>A p.P304H (on ENST00000291707 / NM_053003.4; = p.P186H on NM_033329.2) | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- SIPA1L2 | c.2843C>T p.T948I | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC6A1 | c.1463T>G p.V488G | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SPG7 | c.674A>C p.K225T | Missense Mutation (SNP) | VAF 171/712 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SPRR3 | c.35dup p.P13Tfs*51 | Frame Shift Ins (INS) | VAF 51/317 reads (16%) | called by mutect2, pindel, varscan2
- SYT1 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- TBC1D8 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 105/156 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPC4 | c.1412G>T p.W471L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- UBE2E1 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 105/404 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP54 | c.4075_4087del p.R1359Pfs*80 | Frame Shift Del (DEL) | VAF 41/49 reads (84%) | called by mutect2, pindel, varscan2
- VPS13B | c.11311G>C p.D3771H | Missense Mutation (SNP) | VAF 313/498 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H13 | c.2421C>G p.I807M | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF461 | c.101T>A p.V34E | Missense Mutation (SNP) | VAF 120/327 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF735 | c.437del p.N146Tfs*40 | Frame Shift Del (DEL) | VAF 96/328 reads (29%) | called by mutect2, pindel, varscan2
- ABCC9 | c.1425A>C p.T475= | Silent (SNP) | VAF 138/250 reads (55%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.3183C>T p.D1061= | Silent (SNP) | VAF 127/135 reads (94%) | catalogued as rs1457480819; called by muse, mutect2, varscan2
- AMPH | c.1434A>T p.G478= | Silent (SNP) | VAF 131/538 reads (24%) | called by muse, mutect2, varscan2
- ARNT | c.588T>A p.V196= | Silent (SNP) | VAF 174/702 reads (25%) | called by muse, mutect2, varscan2
- BAIAP3 | c.2574G>A p.T858= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs747822513; called by muse, mutect2, varscan2
- CD28 | c.639C>T p.R213= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as rs142698532; called by muse, mutect2, varscan2
- EMILIN2 | c.336C>T p.G112= | Silent (SNP) | VAF 74/107 reads (69%) | called by muse, mutect2, varscan2
- FAT1 | c.9888G>A p.E3296= | Silent (SNP) | VAF 75/143 reads (52%) | catalogued as COSV101499389; called by muse, mutect2, varscan2
- FGF10 | c.18G>C p.L6= | Silent (SNP) | VAF 78/450 reads (17%) | called by muse, mutect2, varscan2
- FMN2 | c.4872A>G p.Q1624= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as COSV60422561, COSV60449037; called by muse, mutect2, varscan2
- FPR3 | c.747T>C p.S249= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs200983333; called by muse, mutect2, varscan2
- GATAD2A | c.714G>A p.A238= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as rs776225444; called by muse, mutect2, varscan2
- GSX2 | c.444G>A p.A148= | Silent (SNP) | VAF 150/318 reads (47%) | catalogued as COSV100482565; called by muse, mutect2, varscan2
- JPH1 | c.1401G>A p.E467= | Silent (SNP) | VAF 61/242 reads (25%) | called by muse, mutect2, varscan2
- KISS1R | c.813C>T p.L271= | Silent (SNP) | VAF 236/236 reads (100%) | called by muse, mutect2, varscan2
- MRGPRF | c.915G>A p.P305= | Silent (SNP) | VAF 133/536 reads (25%) | catalogued as rs746826672; called by muse, mutect2, varscan2
- MX2 | c.1947T>A p.I649= | Silent (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- NEIL2 | c.372A>G p.A124= | Silent (SNP) | VAF 120/252 reads (48%) | called by muse, varscan2
- NKX1-1 | c.1332C>T p.Y444= | Silent (SNP) | VAF 51/258 reads (20%) | catalogued as rs752511354; called by muse, mutect2, varscan2
- NRXN1 | c.3654G>A p.T1218= | Silent (SNP) | VAF 69/253 reads (27%) | catalogued as rs765748728, COSV60509513; called by muse, mutect2, varscan2
- NRXN1 | c.624G>A p.P208= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV68020987; called by muse, mutect2, varscan2
- NUFIP1 | c.960G>A p.K320= | Silent (SNP) | VAF 122/505 reads (24%) | called by muse, mutect2, varscan2
- OR2B2 | c.429G>A p.Q143= | Silent (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- OR2L13 | c.93C>T p.I31= | Silent (SNP) | VAF 81/298 reads (27%) | called by muse, mutect2, varscan2
- PARD3B | c.516G>A p.Q172= | Silent (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1887C>T p.G629= | Silent (SNP) | VAF 274/275 reads (100%) | catalogued as rs781815602, COSV56548256; called by muse, mutect2, varscan2
- SACS | c.7227A>G p.Q2409= | Silent (SNP) | VAF 77/239 reads (32%) | catalogued as rs752932765; called by muse, mutect2, varscan2
- SF3B1 | c.1725C>T p.L575= | Silent (SNP) | VAF 80/148 reads (54%) | catalogued as rs764654037, COSV59219791; called by muse, mutect2, varscan2
- SMCO2 | c.450C>T p.D150= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as rs367878856; called by muse, mutect2, varscan2
- SNAI2 | c.711T>C p.D237= | Silent (SNP) | VAF 122/270 reads (45%) | catalogued as rs1216935277; called by muse, mutect2, varscan2
- TBC1D32 | c.597A>G p.S199= | Silent (SNP) | VAF 49/225 reads (22%) | called by muse, mutect2, varscan2
- TRIM64C | c.523A>C p.R175= | Silent (SNP) | VAF 88/234 reads (38%) | catalogued as COSV73267151, COSV73267327; called by muse, mutect2, varscan2
- ZNF676 | c.1338T>A p.I446= (on ENST00000650058; = p.I414= on NM_001001411.3) | Silent (SNP) | VAF 70/318 reads (22%) | called by muse, varscan2
- AACS | c.358+1607C>T | Intron (SNP) | VAF 178/423 reads (42%) | called by muse, mutect2
- C19orf84 | c.35+28G>A | Intron (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- CEROX1 | n.2864G>A | RNA (SNP) | VAF 179/717 reads (25%) | called by muse, varscan2
- CHRNA4 | c.*881G>A | 3'UTR (SNP) | VAF 45/177 reads (25%) | called by muse, mutect2, varscan2
- DCHS2 | n.6679_6682dup | RNA (INS) | VAF 49/123 reads (40%) | called by mutect2, pindel, varscan2
- DMGDH | c.-15G>A | 5'UTR (SNP) | VAF 48/207 reads (23%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010430 C>A | 5'Flank (SNP) | VAF 89/255 reads (35%) | called by muse, mutect2, varscan2
- FBXL8 | chr16:67164450 A>T | 3'Flank (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- FCRL2 | c.*14C>A | 3'UTR (SNP) | VAF 46/137 reads (34%) | catalogued as COSV63833717; called by muse, mutect2, varscan2
- FMR1 | c.*129G>A | 3'UTR (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- FOXP2 | c.*3198C>T | 3'UTR (SNP) | VAF 23/141 reads (16%) | catalogued as rs1261779999; called by muse, mutect2, varscan2
- GPR107 | chr9:130141719 A>T | 3'Flank (SNP) | VAF 32/257 reads (12%) | called by muse, mutect2, varscan2
- GPR107 | chr9:130141815 G>A | 3'Flank (SNP) | VAF 44/202 reads (22%) | catalogued as rs1249749346; called by muse, mutect2, varscan2
- HSH2D | c.126-1023T>G | Intron (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
- LHX2 | chr9:124008030 C>A | 5'Flank (SNP) | VAF 46/320 reads (14%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-8276A>T | Intron (SNP) | VAF 82/148 reads (55%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86034C>T | Intron (SNP) | VAF 211/211 reads (100%) | catalogued as rs747384089, COSV72277400, COSV72278078; called by muse, mutect2, varscan2
- MLIP | c.64-9935C>A | Intron (SNP) | VAF 37/218 reads (17%) | called by muse, mutect2, varscan2
- NKAIN4 | c.54+39G>A | Intron (SNP) | VAF 101/335 reads (30%) | catalogued as rs1421070274; called by muse, mutect2, varscan2
- NXPE1 | c.834-900A>C | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- PIP5K1C | c.1920+962G>A | Intron (SNP) | VAF 121/225 reads (54%) | catalogued as rs1374031633; called by muse, mutect2, varscan2
- PPIE | c.*33A>C | 3'UTR (SNP) | VAF 48/178 reads (27%) | called by muse, varscan2
- PYGB | c.1828-596T>A | Intron (SNP) | VAF 41/268 reads (15%) | called by muse, mutect2, varscan2
- RBMS1 | c.1062+45G>T | Intron (SNP) | VAF 38/173 reads (22%) | called by muse, mutect2, varscan2
- TPRX2P | n.820_821del | RNA (DEL) | VAF 63/220 reads (29%) | called by mutect2, pindel, varscan2
- UTS2B | c.*25del | 3'UTR (DEL) | VAF 15/77 reads (19%) | catalogued as rs771807888, COSV100484173; called by mutect2, pindel, varscan2
- ZNF420 | c.*1059dup | 3'UTR (INS) | VAF 71/251 reads (28%) | called by mutect2, varscan2
